Surgical pathology report (de-identified scan), TCGA case TCGA-QR-A6H3, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site National Institutes of Health, specimen TCGA-QR-A6H3-01A (Primary Tumor).

[page 1 of 2]
Surgical Pathology

Final Results

Final

CASE NUMBER:

DIAGNOSIS: Soft tissue mass, paraaortic, resection: Paraganglioma, 6.0 cm.

Immunoperoxidase and in-situ hybridization tests performed here and used for diagnosis were developed and their performance characteristics determined by the [redacted] They have not been cleared or approved by the U.S. Food and Drug Administration. The FDA has also determined that such clearance or approval is not necessary. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA) as qualified to perform high complexity clinical laboratory testing.

CLINICAL INFORMATION: Brief Clinical History: yo M with SDHB mutation to OR today for resection of para-aortic neuroendocrine tumor. Specimen Taken For Protocol: - Yes Allocate Order to Protocol:

PROCEDURE: Operative Findings: 3cm x 3cm mass anterior to the descending aorta at the level of the right atrium was removed, pathology reported as a para-aortic neuroendocrine tumor Post-Operative Diagnosis: para-aortic neuroendocrine tumor Pre-Operative Diagnosis: para-aortic neuroendocrine tumor

SPECIMENS SUBMITTED: 1. TUMOR, Para-aortic Ganglioma

INTRAOPERATIVE CONSULTATION:

Received fresh from the Operating Room labeled with the patient's name, medical record number, date of birth, and further specified as "paraaortic ganglioma" is an intact dome-shaped tan-pink nodular soft tissue fragment measuring 6.0 x 3.5 x 3.0 cm. In the Operating Room, Dr. [redacted] identified the flat surface as the surface abutting the aorta. The flat surface is inked black. The area of concern, prompted out and shared by Dr. [redacted] submitted as 1FS1.

1FS1 diagnosis: Fibroadipose tissue and vessel, no tumor seen.

A representative section of the resection margin is removed and submitted as 1FS2.

1FS2 diagnosis: Neuroendocrine tumor. Representative inked margin suggested by Dr. [redacted] negative for tumor. Approximately 50% of the tissue from the center of the nodule is procured for Dr. Lab.

The diagnosis is made by Dr

The procurement is documented by

GROSS DESCRIPTION:

Requested By:

Do not file in Medical Record

[page 2 of 2]
Received at Surgical Pathology labeled with the patient's name, medical record number, date of birth, and further designated as "paraaortic ganglioma". The remainder of the specimen from frozen section are transferred from the green cassette and submitted entirely in 2 orange cassettes labeled 2S2 and 1FS1.

The specimen consists of a yellow-tan soft tissue fragment measuring 4 x 4 x 3.5 cm. It is well-encapsulated. The cut surface reveals homogeneous fleshy pink-tan cut surface. Representative sections are submitted in 6 white cassettes labeled The remainder of the specimen is put back into the formalin.

Gross Description dictated by

No consultants

Accessioned:

Final Report Signed Out:

<Resident Signature>

<Sign Out Dr. Signature>

Date Report Signed:

Requested By

Do not file in Medical Record

Source: NCI Genomic Data Commons file 5d1c0fc9-3d51-42ef-b9e1-09f60072342e (TCGA-QR-A6H3.4CCFD5B1-5B98-4D56-B06C-0028B55515CE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).